Somatic mutation profile of tumor specimen MP2PRT-PANZUY-TMP1-A (aliquot MP2PRT-PANZUY-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANZUY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (965 days).
Specimen MP2PRT-PANZUY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f4d1b77-6189-40df-bacc-de0eb155ae09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANZUY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANZUY-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b489f5db-ca0e-4691-8d54-a686e6920be1

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDE11A | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 170/389 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs762697508, COSV53693466; called by muse, mutect2, varscan2
- TMEM268 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 196/439 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs1368198568; called by muse, mutect2, varscan2
- ABCA13 | c.1556C>G p.P519R | Missense Mutation (SNP) | VAF 213/450 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- PDS5B | c.4074_4075dup p.P1359Lfs*36 | Frame Shift Ins (INS) | VAF 133/365 reads (36%) | called by mutect2, pindel, varscan2
- IGLL5 | chr22:22899605 CTGTGTCACAGTGTGTGGTATTCGGCGGAGGG>ATTCCCTCGGA | 3'Flank (DEL) | VAF 99/117 reads (85%) | called by pindel, varscan2*
